Surgical pathology report (de-identified scan), TCGA case TCGA-FG-A6IZ, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-A6IZ-01A (Primary Tumor).

[page 1 of 2]
Gender: M DOB: Age:
Phone: Address:

Result Detail

Pathology Result: Surgical Pathology Department

Specimen Collected Date: Specimen Received Date:
Order Number: Ordering Provider:
Medical Record Number Facility:
Status: F

ICD O-3
Oligodendroglioma, grade II 945013

Accession #:
Pathologist:
Date of Procedure:
Date Received:
Date Reported:
Submitting Physician:
Location:

Site: Brain, supratentorial NOS
071.0

Addendum Present

FINAL DIAGNOSIS

- A. ANTERIOR LATERAL MARGIN, BIOPSY:
--CEREBRAL CORTEX, NO SOLID TUMOR IDENTIFIED.
- B. POSTERIOR LATERAL MARGIN-SUPERIOR, BIOPSY:
--CEREBRAL CORTEX AND WHITE MATTER WITH FOCAL HYPERCELLULARITY, NO SOLID TUMOR IDENTIFIED.
- C. POSTERIOR LATERAL MARGIN-INFERIOR, BIOPSY:
--CEREBRAL CORTEX AND WHITE MATTER WITH FOCAL HYPERCELLULARITY, NO SOLID TUMOR IDENTIFIED.
- D. TUMOR CENTER, BIOPSY:
--OLIGODENDROGLIOMA (WHO GRADE II), SEE NOTE.
- E. TUMOR, EXCISION:
--OLIGODENDROGLIOMA (WHO GRADE II), SEE NOTE.

Note: Analysis for chromosome 1p and 19q deletions and immunohistochemistry for mutant IDH1 R132H will be performed and the result reported in an addendum.

gr 10/16/13

Electronically Signed

Out By

Intraoperative Consultation:
Microscopic diagnosis:
FSA1: Cerebral cortex - no solid tumor present.
FSB1: Cerebral cortex with infiltrating glioma.
FSC1: Cerebral cortex, no definitive tumor identified.
Touch prep: High grade glioma.

Addendum/Procedures:
Addendum Date Ordered: Status: Signed Out
Date Complete:
Date Reported:

Addendum Diagnosis
Immunohistochemistry with antibody directed against mutant IDH1 R132H is reactive with the tumor cells.

Electronically Signed Out

Addendum Date Ordered: Status: Signed Out
Date Complete:
Date Reported:

Addendum Diagnosis
Interphase fluorescence in situ hybridization performed at the
Pathology and identified losses of both
chromosomes 1p (1p36) and 19q (19q13).

A copy of the procedure report from the is on file in the

Electronically Signed Out By

Clinical History:
Left intracranial tumor

Specimens Submitted As:
A: ANTERIOR LATERAL MARGIN R/O INVASION
B: POSTERIOR LATERAL MARGIN-SUPERIOR
C: POSTERIOR LATERAL MARGIN-INFERIOR
D: TUMOR CENTER

[page 2 of 2]
K: TUMOR

Gross Description:

A: Received fresh for intraoperative consultation, labelled with patient's name, hospital number, and "anterior lateral margin" are multiple segments of soft tissue measuring 0.6 x 0.5 x 0.2 cm in aggregate. Specimen is submitted entirely for frozen section in one cassette.

B: Received fresh for intraoperative consultation, labelled with patient's name, hospital number, and "posterior lateral margin-superior" is a yellow tan segment of soft tissue measuring 0.8 x 0.5 x 0.2 cm. Specimen is submitted entirely for frozen section in one cassette.

C: Received fresh for intraoperative consultation, labelled with patient's name, hospital number, and "posterior lateral margin-inferior" is a yellow tan segment of soft tissue measuring 1.0 x 0.5 x 0.2 cm. Specimen is submitted entirely for frozen section in one cassette.

D: Received fresh for intraoperative consultation, labelled with patient's name, hospital number, and "tumor center" are multiple segments of soft tissue measuring 2.0 x 1.5 x 0.5 cm in aggregate. Part of the specimen is given to Specimen is submitted entirely in one cassette.

E: Received fresh, post fixed in formalin, labeled with the patient's name and number, and "perm + frozen tumor", are multiple segments of opaque white to pale tan, soft, cerebriform tissue measuring in aggregate 4.0 x 2.5 x 1.5 cm. Submitted entirely in 5 cassettes.

Criteria	W 4/27/13	Yes	
Dual/Syncronous Primary Noted			

Source: NCI Genomic Data Commons file e87f97eb-ac4f-46f3-8d94-fb2de103f659 (TCGA-FG-A6IZ.999D85F3-3DE0-4A08-BCB7-46078C8349A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).